Gene-level copy-number profile of tumor specimen TCGA-A7-A4SF-01A from TCGA case TCGA-A7-A4SF, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.7 years (19,985 days).
Specimen TCGA-A7-A4SF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.2080f468-6807-4c8d-a9d8-99775effd6ba.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A7-A4SF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a38e7aaa-00db-4d9a-a4db-b1b058bdec8f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 2,309; copy number 2: 21,900; copy number 3: 22,431; copy number 4: 6,791; copy number 5: 5,486; copy number 6: 326; copy number 7: 142; copy number 8: 53; copy number 9: 65; copy number 10: 57; copy number 11: 42; copy number 12: 8; copy number 13: 81; copy number 15: 49; copy number 21: 63.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A7-A4SF-01A-11D-A25N-01): tumor purity 0.77, ploidy 2.8, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:58,165,827–58,233,117, 2 genes: LINC02338, LINC00374.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,372 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,327,399–119,356,182, 1 gene, copy number 8 (within-gene range 2–8): LINC01780.
- chr1:119,368,779–120,355,148, 32 genes, copy number 8: HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1.
- chr1:143,343,180–149,048,286, 195 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:154,924,740–248,919,946, 2,096 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr5:102,131,007–102,302,810, 4 genes, copy number 11: RNA5SP188, AC008948.1, SLCO4C1, RN7SKP68.
- chr5:105,922,994–108,382,098, 12 genes, copy number 5 (within-gene range 2–5): RNA5SP189, AC027313.1, AC114940.1, AC114940.2, LINC01950, PSMC1P5, EFNA5, AC024587.2, AC024587.1, RN7SL782P, RN7SKP122, FBXL17.
- chr5:139,526,431–139,645,002, 4 genes, copy number 11 (within-gene range 2–11): UBE2D2, Y_RNA, H3P25, AC113361.1.
- chr5:139,648,999–139,649,728, 1 gene, copy number 11: CXXC5-AS1.
- chr8:91,209,494–93,029,839, 21 genes, copy number 6 (within-gene range 3–6): SLC26A7, AC103409.1, RN7SKP231, PRR13P7, MRPS16P1, RUNX1T1, AF181450.1, AC104339.1, AC022695.1, AC022695.2, AC022695.3, AC091096.1, AC104211.1, AC104211.3, FLJ46284, AC104211.2, AC117834.2, AC117834.1, TRIQK, IRF5P1, MIR8084.
- chr8:135,742,343–141,195,808, 37 genes, copy number 7–8: RNU1-35P, LINC02055, AC103955.1, AC023781.1, RNU6-144P, ZYXP1, AC105213.1, AC110053.1, AC046195.1, AC046195.2, AC079015.1, FAM135B, COL22A1, AC027541.1, AC100807.1, AC100807.2, AC087354.1, AC090093.1, KCNK9, TRAPPC9, AC021744.1, C8orf17, AC040978.1, PEG13, AC107375.1, CHRAC1, AGO2, AC067931.1, AC067931.2, ERICD, PTK2, MIR151A, AC105235.1, RNA5SP278, AC100860.1, DENND3, AC040970.1.
- chr11:73,787,872–83,423,516, 211 genes, copy number 5–6 (within-gene range 3–6) (broad region; genes not listed).
- chr11:83,643,602–83,815,263, 3 genes, copy number 6: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr12:44,244,394–51,515,763, 245 genes, copy number 5 (broad region; genes not listed).
- chr12:65,622,273–78,808,995, 215 genes, copy number 5–15 (broad region; genes not listed).
- chr14:23,699,797–23,934,568, 7 genes, copy number 5: AL160237.1, BRD7P1, AL160237.3, RN7SKP205, AL160237.2, AL136419.2, LINC00596.
- chr15:26,261,669–26,949,208, 8 genes, copy number 6 (within-gene range 4–6): AC012060.1, LINC02248, AC009878.2, GABRB3, AC009878.1, AC011196.1, AC135999.1, GABRA5.
- chr16:11,555–35,912,516, 1,419 genes, copy number 5 (broad region; genes not listed).
- chr17:38,297,023–41,178,221, 157 genes, copy number 6–13 (broad region; genes not listed).
- chr17:51,630,313–57,685,592, 68 genes, copy number 6 (broad region; genes not listed).
- chr17:59,331,655–61,928,016, 75 genes, copy number 8–21 (within-gene range 3–21) (broad region; genes not listed).
- chr17:66,197,693–66,198,238, 1 gene, copy number 10: PSMD7P1.
- chr17:73,513,469–75,856,507, 99 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:35,668,052–64,313,132, 710 genes, copy number 5–8 (broad region; genes not listed).
- chr21:37,593,977–38,307,357, 11 genes, copy number 5 (within-gene range 3–5): AP001407.1, KCNJ6, KCNJ6-AS1, DSCR4, DSCR4-IT1, DSCR8, KCNJ15, AP001425.1, DSCR10, AP001434.1, SPATA20P1.
- chr21:40,212,352–40,385,358, 2 genes, copy number 5: MIR4760, DSCAM-AS1.
- chr21:43,414,483–44,210,114, 28 genes, copy number 5 (within-gene range 3–5): SIK1, LINC00319, LINC00313, AP001048.1, HSF2BP, RPL31P1, H2BS1, MIR6070, RRP1B, PDXK, AP001052.1, AP001053.1, CSTB, TMEM97P1, RRP1, AATBC, MYL6P1, AGPAT3, RNU6-859P, AP001054.1, RNU6-1150P, TRAPPC10, H2AZP1, PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 2,309. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
